Gene-level copy-number profile of specimen HCM-SANG-0310-C15-85A from HCMI case HCM-SANG-0310-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0310-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 783b4ac7-c2af-4443-898f-6dea10ba5980.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0310-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/dac86c4f-a81b-4a51-a219-e7d59e062fce

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,210; copy number 2: 35,925; copy number 3: 14,556; copy number 4: 4,530; copy number 5: 1,196; copy number 6: 231; copy number 7: 37; copy number 8: 181; copy number 10: 6; copy number 11: 9; copy number 15: 5; copy number 21: 3; copy number 33: 10.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,678 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,911,553–121,580,524, 42 genes, copy number 6: NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3, LINC00623, RNVU1-4, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B, SRGAP2C, AC243994.1, SRGAP2-AS1, LINC02798, AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.
- chr1:144,592,868–155,087,538, 468 genes, copy number 5 (broad region; genes not listed).
- chr1:197,902,630–201,970,664, 77 genes, copy number 5 (broad region; genes not listed).
- chr1:227,393,554–232,041,272, 151 genes, copy number 6 (broad region; genes not listed).
- chr3:129,218,093–129,335,074, 9 genes, copy number 5: RPS27P12, COPG1, MIR6826, AC137695.3, HMCES, H1-10, H1-10-AS1, NUP210P3, AC137695.1.
- chr5:58,198–11,904,446, 233 genes, copy number 5 (broad region; genes not listed).
- chr5:40,240,167–42,729,519, 31 genes, copy number 5–10: LINC00604, RNU1-150P, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6, PLCXD3, AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6, AC108099.1, GHR, SERBP1P6, AC093225.1, AC113368.1.
- chr7:7,293,508–7,718,607, 7 genes, copy number 5–7 (within-gene range 4–7): AC079448.1, COL28A1, AC004982.1, AC004982.2, MIOS, AC004948.1, RPA3.
- chr7:13,891,229–14,071,380, 3 genes, copy number 5: ETV1, Y_RNA, RPL6P21.
- chr7:56,493,124–56,526,113, 3 genes, copy number 5: AC092447.8, NMD3P2, AC092447.3.
- chr7:57,650,381–57,837,046, 18 genes, copy number 5–8: AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13.
- chr8:114,791,653–137,105,458, 280 genes, copy number 5–8 (broad region; genes not listed).
- chr11:68,683,779–68,691,175, 1 gene, copy number 5: GAL.
- chr11:69,048,932–69,162,440, 4 genes, copy number 5 (within-gene range 4–5): TPCN2, AP003071.5, MIR3164, AP003071.1.
- chr11:69,371,463–69,481,545, 6 genes, copy number 5: AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747.
- chr11:72,478,221–72,479,237, 1 gene, copy number 5: ART2BP.
- chr11:73,214,998–73,242,427, 2 genes, copy number 5 (within-gene range 4–5): AP002761.1, P2RY2.
- chr11:73,640,479–73,865,133, 7 genes, copy number 5 (within-gene range 4–5): AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243.
- chr11:73,951,026–74,324,705, 14 genes, copy number 5: DNAJB13, AP003717.1, UCP2, AP003717.2, AP003717.3, UCP3, C2CD3, AP002392.1, PPME1, RNA5SP343, AP000577.2, P4HA3, AP000577.1, P4HA3-AS1.
- chr11:74,454,841–74,467,729, 2 genes, copy number 5 (within-gene range 4–5): KCNE3, AP001372.3.
- chr11:74,485,580–75,243,704, 30 genes, copy number 5–6 (within-gene range 4–6): AP001372.4, LIPT2, AP001372.2, POLD3, RANP3, RN7SKP297, CHRDL2, AP001324.3, MIR4696, AP001324.2, AP001324.1, RNF169, XRRA1, AP000560.1, RN7SL239P, AP001992.1, AP001992.2, SPCS2, RNU6-216P, NEU3, AP003175.1, OR2AT2P, NPM1P50, OR2AT4, AP001972.4, SLCO2B1, OR2AT1P, AP001972.3, ZDHHC20P3, TPBGL.
- chr11:75,260,127–75,262,466, 2 genes, copy number 5: AP001972.1, AP001972.5.
- chr11:76,186,325–76,216,025, 3 genes, copy number 5: WNT11, AP000785.1, LINC02761.
- chr11:76,435,559–76,630,465, 5 genes, copy number 5: AP002360.1, EMSY, AP001189.2, LINC02757, AP001189.5.
- chr11:77,066,961–77,126,155, 2 genes, copy number 5: CAPN5, OMP.
- chr11:80,751,200–80,762,826, 1 gene, copy number 5: LINC02720.
- chr11:82,729,940–82,733,864, 1 gene, copy number 5: FAM181B.
- chr11:85,628,573–85,811,159, 5 genes, copy number 5: TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2.
- chr11:87,565,994–87,606,885, 2 genes, copy number 5: AP001784.1, RNU6-1135P.
- chr11:87,847,259–89,498,187, 20 genes, copy number 5: AP000676.5, AP000676.4, AP000676.1, AP005436.3, AP005436.1, AP005436.2, Y_RNA, RAB38, AP001642.1, MIR3166, CTSC, GAPDHP70, GRM5-AS1, GRM5, RNU6-16P, TYR, CBX3P7, AP000720.1, AP000720.2, NOX4.
- chr11:89,797,655–89,949,402, 13 genes, copy number 5: TRIM49, AP004833.1, TRIM53BP, TRIM51BP, AP005435.1, TRIM64B, AP005435.4, AP005435.2, AP005435.3, MTND1P35, TRIM49D1, TRIM49D2, AP004607.3.
- chr12:38,078,529–38,167,631, 6 genes, copy number 7: AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359.
- chr13:29,764,371–31,115,699, 35 genes, copy number 5–6: UBL3, Metazoa_SRP, TIMM8BP1, LINC00297, LINC00572, LINC00544, AL354674.1, LINC00365, LINC00384, LINC00385, AL157770.1, KATNAL1, RNU6-64P, PRDX2P1, LINC00427, LINC00426, AL356750.1, LINC01058, UBE2L5, HMGB1, AL353648.1, RBM22P2, MFAP1P1, PTPN2P2, USPL1, Metazoa_SRP, ALOX5AP, LINC00398, LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066, WDR95P.
- chr13:43,823,909–44,256,596, 14 genes, copy number 5: CCDC122, AL512506.1, LACC1, AL512506.3, AL512506.2, NRAD1, DGKZP1, LINC00390, SMIM2-AS1, SMIM2, SMIM2-IT1, AL589745.2, MIR8079, AL589745.1.
- chr13:57,140,918–57,204,799, 7 genes, copy number 7: PRR20A, PRR20C, PRR20B, PRR20D, PRR20E, PRR20FP, MTCO2P3.
- chr16:18,201,501–19,718,235, 56 genes, copy number 5 (within-gene range 3–5): AC008785.1, AC126755.3, NPIPA8, AC126755.5, PKD1P4, MIR6511A4, AC126755.4, NPIPA9, PKD1P5, MIR6770-3, Y_RNA, AC126755.2, MIR3180-3, MIR3670-3, AC126755.1, MIR3179-3, NOMO2, MIR3670-4, MIR3179-4, AC136618.2, AC136618.1, ABCC6P1, RPS15A, AC138811.2, ARL6IP1, AC138811.1, SMG1, AC092287.1, TMC7, RNU6-1340P, AC099518.4, AC099518.2, COQ7, AC099518.1, AC099518.6, ITPRIPL2, AC099518.3, AC099518.5, SYT17, AC010494.1, CLEC19A, AC130456.1, AC130456.2, AC130456.7, TMC5, AC130456.4, AC130456.3, RNU4-46P, AC130456.5, GDE1, AC130456.6, CCP110, VPS35L, AC002550.2, KNOP1, AC002550.1.
- chr16:29,038,655–29,372,110, 14 genes, copy number 5–6 (within-gene range 3–6): NPIPB10P, AC009093.3, RRN3P2, AC009093.9, AC009093.8, AC009093.10, AC009093.2, AC009093.7, AC009093.1, AC009093.5, AC009093.4, AC009093.6, AC025279.1, AC025279.2.
- chr16:77,433,382–78,066,761, 12 genes, copy number 5 (within-gene range 4–5): AC025284.1, LINC02131, AC092724.1, NUDT7, AC092134.1, VAT1L, AC092134.2, PPIAP50, AC079414.1, CLEC3A, KRT8P22, AC079414.2.
- chr18:22,586,465–23,672,748, 21 genes, copy number 5–7: RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27.
- chr19:27,638,483–31,349,436, 66 genes, copy number 5–33 (within-gene range 3–33) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,802. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
